Somatic mutation profile of tumor specimen MBCProject_1078_T2_WES (aliquot MBCProject_1078_T2_WES_1) from CMI case MBCProject_1078, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 44.8 years (16,378 days).
Specimen MBCProject_1078_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b563876-3ad7-4be2-a6aa-bd53f7dff794.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1078_SALIVA (Saliva), aliquot MBCProject_1078_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0a85afa-9d09-477b-94ec-b3eceeb97694

The open-access MAF lists 38 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 7, 3'UTR 2, Frame Shift Del 1, Nonsense Mutation 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BOLA1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 14/277 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64966676; called by muse, mutect2
- CBFB | c.104G>C p.R35P | Missense Mutation (SNP) | VAF 48/235 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99325520; called by muse, mutect2, varscan2
- CDH1 | c.688-2A>C p.X230_splice | Splice Site (SNP) | VAF 45/226 reads (20%) | catalogued as COSV99028471; called by muse, mutect2, varscan2
- COQ2 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.68); catalogued as rs763562410, CM136889; ClinVar: risk factor; called by muse, mutect2, varscan2
- CUL5 | c.718G>C p.E240Q | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67608703; called by muse, mutect2, varscan2
- CYP2B6 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 52/684 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.048); catalogued as COSV100137593; called by muse, mutect2
- HAS1 | c.1670C>T p.T557M | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs1217318210, COSV55788312; called by muse, mutect2, varscan2
- ITGA11 | c.2509C>T p.R837* | Nonsense Mutation (SNP) | VAF 46/334 reads (14%) | catalogued as rs781751132; called by muse, mutect2, varscan2
- SEZ6L | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs752841877, COSV50658699; called by muse, mutect2, varscan2
- SLC35G2 | c.821T>A p.V274E | Missense Mutation (SNP) | VAF 71/348 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV67588195; called by muse, mutect2, varscan2
- SLC6A7 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.039); catalogued as rs184040183; called by muse, mutect2, varscan2
- SNX8 | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777381644; called by muse, mutect2, varscan2
- SPIDR | c.2407G>A p.G803R | Missense Mutation (SNP) | VAF 50/409 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as rs777795233; called by muse, mutect2, varscan2
- USP17L2 | c.33G>C p.E11D | Missense Mutation (SNP) | VAF 86/850 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs752104464; called by muse, mutect2
- VPS54 | c.2203G>A p.E735K | Missense Mutation (SNP) | VAF 59/432 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as rs1456332803, COSV55444398, COSV99708221; called by muse, mutect2, varscan2
- ATF6 | c.743T>C p.V248A | Missense Mutation (SNP) | VAF 44/512 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.013); called by muse, mutect2
- BCLAF3 | c.97G>C p.G33R | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- CDKN2C | c.49del p.D17Tfs*2 | Frame Shift Del (DEL) | VAF 88/491 reads (18%) | called by mutect2, pindel, varscan2
- CHRM3 | c.925G>A p.G309S | Missense Mutation (SNP) | VAF 42/626 reads (7%) | SIFT tolerated (0.77); PolyPhen benign (0.005); called by muse, mutect2
- CSRP2 | c.159T>A p.D53E | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DST | c.17342A>C p.K5781T (on ENST00000361203 / NM_001374722.1; = p.K3478T on NM_015548.5) | Missense Mutation (SNP) | VAF 45/508 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.108); called by muse, mutect2
- INTS6L | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- KAT2A | c.1931A>C p.D644A | Missense Mutation (SNP) | VAF 87/330 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- KCNC1 | c.50C>T p.T17M | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); called by muse, varscan2
- PAXIP1 | c.197T>G p.F66C | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- PIN4 | c.193G>A p.V65I (on ENST00000664196; = p.V40I on NM_006223.4) | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2
- SHROOM4 | c.370T>A p.F124I | Missense Mutation (SNP) | VAF 35/372 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- TLL1 | c.155A>G p.D52G | Missense Mutation (SNP) | VAF 13/307 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.14); called by muse, mutect2
- ARNT | c.1047C>T p.P349= | Silent (SNP) | VAF 18/424 reads (4%) | called by muse, mutect2
- HERC1 | c.11506T>C p.L3836= | Silent (SNP) | VAF 44/230 reads (19%) | catalogued as rs374945183; called by muse, mutect2, varscan2
- MAST4 | c.3252A>C p.T1084= (on ENST00000403625 / NM_001164664.2; = p.T895= on NM_015183.3) | Silent (SNP) | VAF 99/538 reads (18%) | called by muse, mutect2, varscan2
- MYH7B | c.2472C>T p.L824= | Silent (SNP) | VAF 13/218 reads (6%) | called by muse, mutect2
- PCDH15 | c.1758G>A p.A586= | Silent (SNP) | VAF 89/476 reads (19%) | catalogued as COSV57325855; called by muse, mutect2, varscan2
- THSD4 | c.132C>T p.P44= | Silent (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2
- USP17L1 | c.1386C>T p.N462= | Silent (SNP) | VAF 43/371 reads (12%) | catalogued as rs553328557; called by muse, mutect2, varscan2
- GYS1 | c.-124G>T | 5'UTR (SNP) | VAF 18/78 reads (23%) | called by muse, mutect2, varscan2
- LEMD3 | c.*34A>G | 3'UTR (SNP) | VAF 52/298 reads (17%) | called by muse, mutect2, varscan2
- MPDU1 | c.*32C>T | 3'UTR (SNP) | VAF 50/536 reads (9%) | called by muse, mutect2
